Surgical pathology report (de-identified scan), TCGA case TCGA-FP-8631, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-8631-01A (Primary Tumor).

[page 1 of 4]
Pre-Operative/Clinical History

Esophageal gastric tumor

Specimen(s) Received

A: GE JUNCTION TUMOR

Gross Description

Specimen A received fresh for a frozen section labeled "GE junction".

Specimen type/procedure:

Partial esophagogastrrectomy.

Specimen description/measurement:

Esophagus:

10.0 cm in length x 3.5 cm mucosal circumference, wall thickness 0.4 cm.

Stomach:

5.0 cm in length x 7.0 cm in diameter (14.0 cm mucosal circumference), wall thickness 0.4 cm.

Detached fragment:

3.5 cm in diameter with a wall thickness of 0.4 cm.

The specimen is received intact with several lymph nodes adjacent to the lesser curvature omentum. There is a staple margin designated as the celiac region.

Tumor site:

Predominantly cardia region, involving the GE junction and extending 2.0 cm above the GE junction. The epicenter of the tumor is 0.5 cm inferior to the GE junction in the cardia. No obvious Barrett's is seen.

Tumor size:

6.5 cm x 5.0 cm in length with a maximum thickness of 1.8 cm.

Tumor configuration:

Raised borders with a bulky appearance and an ulcerated center. The tumor occupies approximately 80% of the mucosal circumference at the GE junction.

Depth of invasion:

The tumor invades through the muscularis wall coming to within 0.1 cm of the black-inked deep margin.

Surgical margins:

Proximal margin:

8.0 cm.

Distal margin:

2.4 cm.

Omental (radial) margins:

4.0 cm.

Deep margin (black):

0.1 cm.

Lymph nodes:

[page 2 of 4]
Esophagus:

Several lymph nodes are identified, largest up to 0.5 cm, grossly.

Stomach:

There are several lymph nodes identified, largest up to 1.3 cm at the celiac region.

Sections:

- (A1FS) Frozen section of tumor resubmitted
- (A2) Proximal esophageal margin, en face
- (A3-A5) Distal gastric margin, perpendicular section, closest to tumor (blue ink marks true margin)
- (A6) Additional distal margin, en face
- (A7-8) Radial margin at staple line, en face
- (A9, A10) Detached ring-shaped tissue fragment
- (A11-A16) Tumor with deepest point of invasion
- (A17) Tumor at GE junction
- (A18) Random representative section of esophagus away from tumor
- (A19) Random section of uninvolved GE junction
- (A20) Random section of uninvolved stomach
- (A21) Additional section of tumor and adjacent vessels
- (A22) Lymph node candidates, upper esophagus
- (A23) One lymph node bisected, mid esophagus
- (A24) Several intact lymph nodes, mid esophagus
- (A25) Lymph node candidates, lower esophagus
- (A26) Highest celiac region lymph node bisected (adjacent to staple line)
- (A27, A28) Several lymph nodes at the celiac region, (adjacent to the staple line)
- (A29) Lymph node candidates adjacent to tumor, stomach
- (A30-31) Lymph nodes distal to tumor, stomach.

Intraoperative Consultation

Specimen A, frozen section of tumor with a diagnosis of "adenocarcinoma" is rendered by

Microscopic Description

In the AJCC Cancer Staging Manual, cancers whose epicenter is within the proximal 5.0 cm of the cardia and that extend into the gastroesophageal junction and esophagus are staged under esophageal/ gastroesophageal junction tumors.

Summary of Pathologic Findings

- Specimen:** Partial esophagogastrectomy (Distal 10 cm of esophagus).
- Procedure:** Esophagogastrectomy.
- Tumor site:** Gastric cardia and gastroesophageal junction with the epicenter of the tumor 0.5 cm inferior to the gastroesophageal junction.
- Relationship of tumor to esophagogastric junction:** The mid point lies in the proximal stomach.
- Distance of tumor center from EG junction:** 0.5 cm inferior to EG junction.
- Tumor size:** 6.5 x 5.0 cm.
- Histologic type:** Adenocarcinoma.

[page 3 of 4]
Histologic grade: Moderately differentiated (intestinal type).

Microscopic tumor extension: The bulk of the tumor is within the gastric cardia. However, it does involve the gastroesophageal junction and extends into the distal esophagus, undermining the mucosa in the distal esophagus. Within the gastric portion, the tumor invades through the muscularis propria into the subserosal fat without penetration of the serosa. Within the distal esophageal portion of tumor, tumor invades through the muscularis propria into the adventitia.

Proximal margin: Uninvolved by invasive carcinoma.
Uninvolved by dysplasia.

Distal margin: Uninvolved by invasive carcinoma.
Uninvolved by dysplasia.

Adventitial margin: Closely approximating the adventitial margin at less than 1 mm.

Distance of invasive carcinoma from closest margin: less than 1 mm from adventitial margin

Specify closest margin: Distal esophageal adventitial margin.

Distance of tumor from distal margin: 1.4 cm.

Distance of tumor from proximal margin: 8.0 cm.

Treatment effect: No prior treatment.

Lymph-vascular invasion: Present.

Regional lymph nodes:

Number examined: 25.

Number involved: 6.

No extracapsular extension is seen. The site of involvement of the lymph nodes is as follows:

Upper esophagus: 1 lymph node, no tumor seen.

Mid esophagus: 2 of 7 lymph nodes with metastatic carcinoma.

Lower esophagus: 1 of 1 lymph node with metastatic carcinoma.

Gastric celiac region: 1 of 8 lymph nodes with metastatic carcinoma.

Gastric adjacent to tumor: 2 of 8 lymph nodes with metastatic carcinoma.

Perineural invasion: Present.

Pathologic staging (pTNM): pT3 N2 (according to the AJCC [redacted] this tumor is staged under esophageal/ Gastroesophageal junction tumors).

Additional pathologic findings:

Extensive sampling of the tumor show a moderately differentiated adenocarcinoma predominantly within the gastric cardia, but involving the gastroesophageal junction and extending into the distal esophagus for a length of 2.0 cm. Specialized metaplasia is not seen in sections of the esophageal portion of tumor. There is a single small microscopic focus of specialized metaplasia seen in one area of the gastroesophageal junction at the cardia side. The finding of a single microscopic focus of specialized metaplasia at the cardia portion of the GE junction does not denote Barrett's esophagus, since specialized metaplasia can occur within the cardia. Noninvolved gastric mucosa is unremarkable without significant inflammation.

[page 4 of 4]
Diagnosis

DISTAL ESOPHAGUS AND STOMACH, ESOPHAGOGASTECTOMY:
MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH EXTENSION THROUGH MUSCULARIS
PROPRIA TO INVOLVE ADVENTITIA.
ADENOCARCINOMA LESS THAN 1 MM FROM ADVENTITIAL MARGIN.
SIX OF TWENTY-FIVE LYMPH NODES WITH METASTATIC ADENOCARCINOMA.
SEE MICROSCOPIC DESCRIPTION.

Procedures/Addenda

ADDENDUM

Addendum Comment

Her-2 immunostains are performed on sections of the adenocarcinoma and show 3+ positive staining.

Source: NCI Genomic Data Commons file f7440d60-4da5-43e9-a313-a7c254dd40c4 (TCGA-FP-8631.D5A17F86-A18A-4EC5-BD4C-7C31E4C26D3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).